Somatic mutation profile of tumor specimen TCGA-IZ-A6M8-01A (aliquot TCGA-IZ-A6M8-01A-11D-A31X-10) from TCGA case TCGA-IZ-A6M8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.9 years (25,545 days).
Specimen TCGA-IZ-A6M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a33ac87a-54aa-48dd-974c-81d2e9eefe0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IZ-A6M8-10A (Blood Derived Normal), aliquot TCGA-IZ-A6M8-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d57d6d-d2c4-4511-adf3-e3fd1b3ddedf

The open-access MAF lists 82 somatic variants for this specimen: 56 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 44, Silent 26, Frame Shift Del 7, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF2BPL | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1566785990, COSV53149406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65535593; called by muse, mutect2, varscan2
- ABHD13 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65535596; called by muse, mutect2, varscan2
- ABL2 | c.3433C>A p.L1145I (on ENST00000502732 / NM_007314.4; = p.L1130I on NM_005158.5) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.996); catalogued as COSV61021698; called by muse, mutect2, varscan2
- ACOX1 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV53137993; called by muse, mutect2, varscan2
- ADGRL4 | c.113del p.G38Efs*28 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as COSV66062240; called by mutect2, pindel, varscan2
- AMHR2 | c.1479A>T p.E493D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57687298; called by muse, varscan2
- APOBR | c.3164C>G p.P1055R (on ENST00000431282; = p.P1064R on NM_018690.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100112974, COSV60494727; called by muse, mutect2, varscan2
- ATP7A | c.2188T>A p.Y730N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV58455825; called by muse, varscan2
- CDH4 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV64678941; called by muse, mutect2, varscan2
- CFAP221 | c.1053A>C p.K351N | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV54664316; called by muse, mutect2, varscan2
- DNAAF5 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV52422367; called by muse, mutect2, varscan2
- DNAJC13 | c.3454T>C p.F1152L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as COSV53459971; called by muse, mutect2, varscan2
- EXOC1 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.53); catalogued as COSV62122342; called by muse, mutect2, varscan2
- FASN | c.1871-1G>C p.X624_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as COSV60762495; called by muse, mutect2
- GID4 | c.688T>A p.Y230N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV52010609; called by muse, mutect2, varscan2
- GMCL1 | c.1361T>G p.F454C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57003825; called by muse, mutect2, varscan2
- GRB10 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.011); catalogued as COSV100239638; called by muse, mutect2
- GRIN2B | c.1609A>G p.M537V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV74204657; called by muse, mutect2, varscan2
- HFE | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as CM112341, COSV58513426, COSV58514178; called by muse, mutect2, varscan2
- HSPBAP1 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60244512; called by muse, mutect2, varscan2
- IGSF22 | c.2553G>T p.K851N (on ENST00000319338; = p.K952N on NM_173588.4) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV55012145; called by muse, mutect2, varscan2
- IHH | c.869T>C p.F290S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.556); catalogued as rs1375466917, COSV55394195; called by muse, mutect2, varscan2
- IPP | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV63434373; called by muse, mutect2, varscan2
- LBR | c.960T>G p.H320Q | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs1408746181, COSV55292368; called by muse, mutect2, varscan2
- MCOLN3 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62013954, COSV62016677; called by muse, mutect2, varscan2
- MEGF10 | c.412+1G>T p.X138_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV57257908; called by muse, mutect2, varscan2
- MUC16 | c.29575C>T p.P9859S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.862); catalogued as COSV67501737; called by muse, mutect2, varscan2
- NBEA | c.2789A>G p.Y930C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59831007; called by muse, mutect2, varscan2
- NSD2 | c.3568G>C p.V1190L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV56397883; called by muse, mutect2, varscan2
- ORC3 | c.1454A>T p.N485I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57644309; called by muse, mutect2, varscan2
- PLEKHG1 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV62051905; called by muse, mutect2, varscan2
- PROSER2 | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs987534473, COSV53208328; called by muse, varscan2
- PTPN23 | c.3029C>G p.P1010R | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.308); catalogued as COSV99650145; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3259C>G p.P1087A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as rs1342545769, COSV54764843; called by muse, mutect2, varscan2
- RNF123 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.146); catalogued as COSV59693362; called by muse, mutect2, varscan2
- RUNX1T1 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); catalogued as rs1452425691, COSV99749192; called by mutect2, varscan2
- SBNO1 | c.977G>C p.G326A (on ENST00000420886; = p.G325A on NM_018183.5) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57346915; called by muse, mutect2, varscan2
- SCN1A | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57691803, COSV57691814; called by muse, mutect2, varscan2
- SNX6 | c.712G>T p.D238Y (on ENST00000652385; = p.D110Y on NM_021249.5) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61920943; called by muse, mutect2, varscan2
- TARBP2 | c.1009T>C p.C337R (on ENST00000266987 / NM_134323.2; = p.C316R on NM_004178.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57200972; called by muse, mutect2, varscan2
- TESK2 | c.796T>A p.F266I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59158348; called by muse, mutect2, varscan2
- TPP2 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65755342; called by muse, varscan2
- TRIM45 | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56715234; called by muse, mutect2, varscan2
- WDR19 | c.597A>C p.E199D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV56470987; called by muse, mutect2, varscan2
- ZNF45 | c.542T>G p.I181S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs757150484, COSV54195008; called by muse, mutect2, varscan2
- ZNF534 | c.370T>A p.L124I (on ENST00000332323 / NM_001143939.3; = p.L111I on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV56521868; called by muse, mutect2, varscan2
- CFAP57 | c.1779_1782del p.F593Lfs*15 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- DCHS1 | c.3725del p.K1242Rfs*15 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- MEFV | c.897del p.E299Dfs*69 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- MON2 | c.2130del p.W710* | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- PIK3CG | c.579del p.K194Sfs*9 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- SETDB1 | c.149_157del p.K50_C53delinsS | In Frame Del (DEL) | VAF 66/227 reads (29%) | called by mutect2, pindel, varscan2
- SULT6B1 | c.235dup p.I79Nfs*6 (on ENST00000535679 / NM_001367551.1; = p.I41Nfs*6 on NM_001032377.2) | Frame Shift Ins (INS) | VAF 38/96 reads (40%) | called by mutect2, varscan2
- TEX14 | c.1806_1807del p.P603Lfs*38 (on ENST00000240361 / NM_001201457.2; = p.P597Lfs*38 on NM_031272.5) | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- TOP2A | c.1835dup p.Y612* | Nonsense Mutation (INS) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- CARM1 | c.531G>A p.L177= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59004014; called by muse, mutect2, varscan2
- CASZ1 | c.2451C>T p.T817= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs1273717302, COSV59742062; called by muse, mutect2, varscan2
- CASZ1 | c.1686C>T p.Y562= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as rs770390648, COSV59742068; called by muse, mutect2, varscan2
- CDK13 | c.4299T>C p.P1433= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV51707840; called by muse, varscan2
- CORO6 | c.126C>T p.V42= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV52183095; called by muse, mutect2, varscan2
- CRNKL1 | c.318C>T p.A106= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs140622884; called by muse, mutect2, varscan2
- DMXL1 | c.2397T>C p.F799= | Silent (SNP) | VAF 92/284 reads (32%) | catalogued as COSV60722930; called by muse, mutect2, varscan2
- DNM1 | c.669G>A p.K223= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as COSV57856973; called by muse, mutect2, varscan2
- DOCK8 | c.5439C>T p.V1813= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV66624598; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.48C>T p.F16= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV55745970; called by muse, mutect2, varscan2
- EFCAB1 | c.16C>T p.L6= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV50620455; called by muse, mutect2, varscan2
- ENTPD4 | c.1116C>T p.D372= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs1371902516, COSV62270551; called by muse, mutect2, varscan2
- GDA | c.633A>G p.T211= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52998797; called by muse, mutect2, varscan2
- HMG20A | c.84C>G p.T28= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60314617; called by muse, mutect2, varscan2
- IL17RD | c.933G>A p.S311= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs776069493, COSV56344064; called by muse, mutect2, varscan2
- KDM1A | c.687G>A p.L229= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV100752413, COSV63091158; called by muse, mutect2, varscan2
- LTBP2 | c.1272G>C p.G424= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV56215208; called by muse, mutect2, varscan2
- MAMDC4 | c.720C>T p.V240= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV56035364; called by muse, mutect2, varscan2
- PLCH2 | c.894G>A p.G298= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV53951145; called by muse, mutect2, varscan2
- PRKACG | c.720C>T p.Y240= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV55255016; called by muse, mutect2, varscan2
- SDK1 | c.2427C>T p.R809= | Silent (SNP) | VAF 57/107 reads (53%) | catalogued as COSV67355919; called by muse, mutect2, varscan2
- SF3B3 | c.3519G>A p.V1173= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV56791755; called by muse, mutect2, varscan2
- TJP1 | c.2214A>C p.T738= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV62047427; called by muse, mutect2, varscan2
- TM9SF4 | c.621C>T p.F207= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs775400117, COSV54104557; called by muse, mutect2, varscan2
- TTC5 | c.45A>G p.K15= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV51872578; called by mutect2, varscan2
- ZNF281 | c.570G>A p.Q190= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54168493, COSV54170353, COSV99664246; called by muse, mutect2, varscan2
